Somatic mutation profile of tumor specimen 0DELKB from CCDI case PBBPYS, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioma, malignant; Tissue or organ of origin: Temporal lobe; Age at diagnosis: 7.8 years (2,858 days).
Specimen 0DELKB: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f9071fe2-d62a-40ba-bb4a-180361937840.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DELJ5 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/face6b29-8777-49cb-a706-6415b24244a0

The open-access MAF lists 30 somatic variants for this specimen: 11 protein-altering or splice-affecting, 3 silent, 16 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 10, Intron 9, Silent 3, 3'Flank 2, 3'UTR 2, 5'UTR 2, RNA 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- H3C2 | c.83A>T p.K28M | Missense Mutation (SNP) | VAF 119/271 reads (44%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.879); catalogued as COSV52517710, COSV52518111; called by muse, mutect2, varscan2
- PTPN11 | c.854T>C p.F285S | Missense Mutation (SNP) | VAF 60/135 reads (44%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121918463, CM021134, CM060447, COSV61005134; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.422G>A p.C141Y | Missense Mutation (SNP) | VAF 90/101 reads (89%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs587781288, CM993216, COSV52664953, COSV52926626, COSV53155598; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- FLG | c.5395G>A p.D1799N | Missense Mutation (SNP) | VAF 83/181 reads (46%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.76); catalogued as rs1322374691, COSV100911673, COSV64240228; called by muse, mutect2, varscan2
- GINS4 | c.341G>A p.R114H | Missense Mutation (SNP) | VAF 195/412 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.714); catalogued as rs1239038975; called by muse, mutect2, varscan2
- STAG2 | c.1821+1G>A p.X607_splice | Splice Site (SNP) | VAF 158/161 reads (98%) | catalogued as COSV54372561, COSV54376496; called by muse, mutect2, varscan2
- AP3M1 | c.1067G>T p.G356V | Missense Mutation (SNP) | VAF 21/400 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- HLCS | c.313A>G p.S105G | Missense Mutation (SNP) | VAF 49/333 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.752); called by muse, mutect2, varscan2
- MUC16 | c.20361T>G p.I6787M | Missense Mutation (SNP) | VAF 81/177 reads (46%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- TGFBR1 | c.1154A>T p.D385V | Missense Mutation (SNP) | VAF 139/284 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- VSTM2B | c.593G>A p.G198D | Missense Mutation (SNP) | VAF 14/110 reads (13%) | SIFT tolerated (0.18); PolyPhen benign (0); called by muse, varscan2
- ARFGAP3 | c.756G>A p.A252= | Silent (SNP) | VAF 64/476 reads (13%) | catalogued as rs145699759; called by muse, mutect2, varscan2
- HIVEP1 | c.3468A>G p.R1156= | Silent (SNP) | VAF 106/338 reads (31%) | called by muse, mutect2, varscan2
- SLC22A18AS | c.474G>T p.G158= | Silent (SNP) | VAF 22/207 reads (11%) | called by muse, mutect2
- CCDC162P | n.3215C>T | RNA (SNP) | VAF 133/266 reads (50%) | catalogued as rs770783105; called by muse, mutect2, varscan2
- CEP43 | c.301-88G>A | Intron (SNP) | VAF 5/32 reads (16%) | called by muse, mutect2, varscan2
- CRIPT | c.*53T>A | 3'UTR (SNP) | VAF 26/212 reads (12%) | called by muse, varscan2
- EPHB4 | c.2484+51G>T | Intron (SNP) | VAF 41/96 reads (43%) | called by mutect2, varscan2
- HERC1 | c.13689-48A>T | Intron (SNP) | VAF 6/26 reads (23%) | called by muse, mutect2
- NIPBL | c.6955-84C>G | Intron (SNP) | VAF 4/35 reads (11%) | called by muse, varscan2
- PTGR1 | c.209+72G>C | Intron (SNP) | VAF 8/160 reads (5%) | called by muse, mutect2
- RMI1 | c.-9T>A | 5'UTR (SNP) | VAF 10/96 reads (10%) | called by muse, varscan2
- SF3A2 | c.*15C>A | 3'UTR (SNP) | VAF 6/94 reads (6%) | called by muse, mutect2
- SLC35B1 | c.767-81G>C | Intron (SNP) | VAF 5/24 reads (21%) | catalogued as rs1184142130, COSV53604513; called by muse, mutect2, varscan2
- SPIDR | c.1545-92_1545-89del | Intron (DEL) | VAF 4/20 reads (20%) | called by mutect2, varscan2
- TCHHL1 | chr1:152080632 C>T | 3'Flank (SNP) | VAF 115/259 reads (44%) | catalogued as rs573955610; called by muse, mutect2, varscan2
- TMEM181 | chr6:158536426 del GGCGGATGGGCGCGGA | 5'UTR (DEL) | VAF 40/124 reads (32%) | catalogued as rs879527986; called by mutect2, varscan2
- TTC8 | c.459+44T>A | Intron (SNP) | VAF 8/70 reads (11%) | called by muse, varscan2
- USP11 | c.1533+59C>T | Intron (SNP) | VAF 56/57 reads (98%) | called by muse, mutect2, varscan2
- WDR87 | chr19:37884900 A>G | 3'Flank (SNP) | VAF 14/73 reads (19%) | catalogued as rs747918311; called by mutect2, varscan2
